Gene-level copy-number profile of tumor specimen SM-JU33S from CPTAC case C524103, project CPTAC-3 (Other and unspecified urinary organs — Nevi and Melanomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Urethra.
Specimen SM-JU33S: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Cerebrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1c952c67-d409-4427-ba73-a25d12db13a8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator 1105274 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,391 have no estimate.
https://portal.gdc.cancer.gov/files/8397773d-3f2d-48cd-8629-19bdd727ab85

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 110; copy number 1: 25,841; copy number 2: 25,350; copy number 3: 6,050; copy number 4: 806; copy number 5: 75.

Homozygous deletions (total copy number 0; autosomes only): 110 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:248,601,416–248,937,043, 19 genes: AC098483.2, OR2T11, OR2T35, OR2T27, CR589904.2, OR14I1, LYPD9P, CR589904.1, AHCYP8, LYPD8, DPY19L4P1, SH3BP5L, MIR3124, ZNF672, ZNF692, AL672291.1, PGBD2, RNU6-1205P, RPL23AP25.
- chr2:38,814–46,870, 1 gene: FAM110C.
- chr4:49,096–205,009, 6 genes: BNIP3P41, ZNF595, AC253576.1, ZNF718, AC253576.2, AC108475.1.
- chr4:47,831,330–49,246,915, 29 genes (within-gene range 0–2): AC107068.2, AC107068.1, NFXL1, NIPAL1, CNGA1, TXK, RNU6-838P, U6, TEC, Y_RNA, SLAIN2, SLC10A4, ZAR1, FRYL, RNU5E-3P, OCIAD1, OCIAD1-AS1, OCIAD2, RNU6-158P, AC020593.1, CWH43, TPI1P4, AC118282.3, AC118282.2, AC118282.4, SNX18P23, AC118282.1, MTCO3P39, MTND3P22.
- chr7:63,621,090–63,636,617, 2 genes: MIR4283-2, AC006015.1.
- chr8:12,128,107–12,151,134, 4 genes (within-gene range 0–1): AC130366.1, USP17L7, USP17L2, DEFB109D.
- chr15:101,903,154–101,979,093, 10 genes: AC140725.2, OR4F4, OR4G2P, OR4G6P, FAM138E, AC140725.1, MIR1302-10, WASH3P, MIR6859-3, DDX11L9.
- chr16:67,028,984–67,101,058, 1 gene: CBFB.
- chr17:142,789–414,023, 8 genes (within-gene range 0–1): DOC2B, LINC02091, RPH3AL, AC129507.4, AC129507.1, AC129507.2, AC129507.3, AC141424.1.
- chr17:31,303,770–31,321,749, 3 genes (within-gene range 0–1): EVI2B, AC134669.1, EVI2A.
- chr17:31,391,675–31,713,853, 14 genes: RAB11FIP4, RN7SL79P, RN7SL45P, AC003101.3, MIR4724, MIR193A, AC003101.2, RNU6ATAC7P, AC003101.1, MIR4725, MIR365B, AC007923.3, AC007923.2, RNU6-1134P.
- chr18:80,157,232–80,247,514, 1 gene (within-gene range 0–1): PARD6G.
- chr18:80,183,680–80,202,992, 1 gene: AC139100.1.
- chr19:43,192,702–43,269,530, 3 genes: PSG4, CEACAMP10, PSG9.
- chr21:9,026,821–9,376,645, 8 genes: CDRT15P9, CR392039.4, TEKT4P2, SOWAHCP2, CR392039.2, CR381653.1, SNX18P12, CR381653.2.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 6,910 genes in 58 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:3,059,615–3,652,761, 15 genes, copy number 3 (within-gene range 1–3): PRDM16-DT, PRDM16, MIR4251, AL008733.1, AL512383.1, AL590438.1, AL354743.2, AL354743.1, ARHGEF16, AL512413.1, MEGF6, MIR551A, AL513320.1, TPRG1L, WRAP73.
- chr1:41,241,772–107,965,180, 1,128 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr2:193,256,483–198,772,356, 62 genes, copy number 3 (broad region; genes not listed).
- chr3:58,008,400–79,767,998, 229 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr4:212,610–5,019,458, 145 genes, copy number 3–5 (broad region; genes not listed).
- chr4:29,907,659–35,496,003, 28 genes, copy number 3: AC097510.1, RPS3AP17, AC106868.1, AC098595.1, PCDH7, AC097716.1, MTCYBP43, LINC02497, AC104071.1, LINC02501, LINC02506, AC097654.1, LINC02353, MAPRE1P2, AC093878.1, AC097535.2, AC097535.1, AC079772.1, AC016687.3, AC016687.2, AC016687.1, LINC02484, AC110790.1, AC093689.1, AC093913.1, AC020589.1, SEC63P2, RNU6-573P.
- chr4:176,213,673–177,301,253, 9 genes, copy number 3 (within-gene range 2–3): ASB5, SPCS3-AS1, SPCS3, AC093801.2, AC093801.1, VEGFC, AC097518.2, AC092673.1, LINC02509.
- chr4:188,349,376–189,709,714, 18 genes, copy number 3: AC093789.1, ICE2P1, LINC01060, AC093909.3, AC093909.5, RNU7-192P, AC093909.1, AC093909.6, AC093909.2, LINC02508, AC093909.4, AC122138.1, AC107391.1, AC105924.1, HSP90AA4P, LINC01262, AF250324.1, RNU1-51P.
- chr5:58,198–23,014,527, 365 genes, copy number 3 (broad region; genes not listed).
- chr5:31,053,565–31,555,053, 8 genes, copy number 3: RPL19P11, AC026421.1, AC113386.1, CDH6, DUX4L51, DROSHA, Y_RNA, C5orf22.
- chr5:64,404,512–65,587,549, 18 genes, copy number 3: AC091862.1, RGS7BP, RN7SL169P, RNU6-294P, MRPL49P1, SHISAL2B, SREK1IP1, CWC27, AC092354.2, AC092354.1, Y_RNA, ADAMTS6, AC008868.1, RPEP1, AC025186.1, AC025176.1, CENPK, PPWD1.
- chr5:72,574,120–77,166,909, 106 genes, copy number 3–4 (broad region; genes not listed).
- chr7:7,640,711–9,189,857, 20 genes, copy number 4 (within-gene range 2–4): UMAD1, AC007161.3, AC007161.2, AC007161.1, RNU6-534P, CCNB2P1, AC006042.3, GLCCI1-DT, GLCCI1, AC006042.2, ICA1, AC006042.1, AC007009.1, AC007128.1, AC007128.2, NXPH1, AC009500.1, AC004852.2, AC004852.1, AC004852.3.
- chr8:46,549,089–52,022,974, 83 genes, copy number 3–5 (broad region; genes not listed).
- chr8:65,526,738–67,407,072, 43 genes, copy number 3: LINC01299, AC100814.1, Y_RNA, ARMC1, MTFR1, AC055822.1, PDE7A, AC100812.1, DNAJC5B, AC084082.1, TRIM55, CRH, LINC00967, AC009879.4, RRS1-AS1, RRS1, AC009879.2, AC009879.3, ADHFE1, AC009879.1, VXN, RNU6-1324P, MYBL1, VCPIP1, Y_RNA, C8orf44-SGK3, C8orf44, SGK3, PTTG3P, MCMDC2, SNHG6, SNORD87, TCF24, PPP1R42, AC110998.1, COPS5, CSPP1, RNA5SP268, AC087359.1, ARFGEF1, AC021321.2, AC021321.1, AC011037.1.
- chr8:72,537,225–73,441,526, 21 genes, copy number 3 (within-gene range 2–3): KCNB2, HAUS1P3, AC013562.2, AC013562.1, AC090735.1, AC022893.2, TERF1, RNU6-285P, AC022893.3, AC022893.1, SBSPON, AC100823.1, AC100823.2, C8orf89, PRXL2AP2, RPL7, RDH10, RDH10-AS1, AC111149.1, AC111149.2, STAU2-AS1.
- chr8:74,599,775–74,896,302, 8 genes, copy number 3: MIR2052HG, PCBP2P2, AC115837.1, MIR2052, AC011632.1, AC026616.1, PI15, AC011632.2.
- chr8:78,148,101–80,539,135, 38 genes, copy number 3: AC084706.1, PKIA-AS1, RNU6-1220P, PKIA, AC068700.1, ZC2HC1A, IL7, AC100854.1, THAP12P7, AC083837.1, LINC02605, AC138646.1, AC100870.1, RPL3P9, STMN2, HEY1, LINC01607, AC036214.1, RNU7-85P, AC036214.4, MRPS28, AC036214.3, AC036214.2, AC009686.2, TPD52, AC009686.1, RN7SL41P, MIR5708, AC104212.3, AC034114.2, AC104212.2, AC104212.1, AC034114.1, RNU6-1213P, AC009812.1, Y_RNA, ZBTB10, AC009812.3.
- chr8:90,592,804–101,208,558, 210 genes, copy number 3–4 (broad region; genes not listed).
- chr8:102,125,432–117,318,701, 156 genes, copy number 3 (broad region; genes not listed).
- chr8:122,414,332–123,541,206, 36 genes, copy number 3: SMILR, LINC01151, AC108136.1, AC100872.1, AC100872.2, CDK5P1, AC016405.3, AC016405.2, ZHX2, AC016405.1, AC104316.2, AC104316.1, DERL1, TBC1D31, HMGB1P19, FAM83A, U3, AC068228.1, AC068228.2, FAM83A-AS1, MIR4663, C8orf76, ZHX1-C8orf76, UBA52P5, ZHX1, RNU6-628P, AC018992.1, ATAD2, RNU6-875P, MIR548AA1, MIR548D1, DUTP2, IMPDH1P6, NTAQ1, U4, FBXO32.
- chr8:123,984,138–145,066,685, 384 genes, copy number 3–4 (broad region; genes not listed).
- chr10:42,979,017–43,525,217, 16 genes, copy number 3: LINC01264, MIR5100, RET, AC010864.1, CSGALNACT2, RASGEF1A, LINC02633, AC068707.1, RNU6ATAC11P, FXYD4, HNRNPF, SNORD3J, AL450326.1, ZNF487, RNU7-193P, AL450326.2.
- chr11:1,983,237–2,270,952, 16 genes, copy number 3 (within-gene range 2–3): MRPL23-AS1, LINC01219, H19, AC051649.3, MIR675, AC051649.2, IGF2, AC132217.2, AC132217.1, INS-IGF2, MIR483, IGF2-AS, INS, TH, MIR4686, ASCL2.
- chr11:54,591,480–56,361,511, 92 genes, copy number 3 (broad region; genes not listed).
- chr11:56,597,426–63,048,126, 324 genes, copy number 3 (broad region; genes not listed).
- chr11:118,606,440–118,791,164, 9 genes, copy number 3: PHLDB1, AP000941.1, MIR6716, TREH, TREHP1, AP002954.1, RNU6-376P, AP002954.2, DDX6.
- chr11:124,476,963–124,834,487, 22 genes, copy number 3: OR8B9P, OR8B10P, OR8A3P, AP000916.1, OR8B12, OR8A1, OR8Q1P, PANX3, TBRG1, SIAE, RNA5SP352, SPA17, NRGN, AP000866.5, VSIG2, ESAM, AP000866.2, MSANTD2, AP000866.6, AP000866.3, AP000866.1, AP000866.4.
- chr11:129,761,713–130,403,657, 18 genes, copy number 3: AP003327.2, AP003327.1, TMEM45B, NFRKB, PRDM10, LINC00167, AP003041.1, ELOBP2, AP003041.2, APLP2, RPL34P21, U4, ST14, ZBTB44, NDUFAF2P2, DDX18P5, RN7SL778P, ZBTB44-DT.
- chr12:17,383,352–23,251,499, 79 genes, copy number 3 (broad region; genes not listed).
- chr14:21,698,954–22,086,961, 37 genes, copy number 3: AC243972.3, TRAV2, AC243972.1, TRAV3, TRAV4, TRAV5, RPL4P1, TRAV6, TRAV7, TRAV8-1, TRAV9-1, TRAV10, TRAV11, TRAV12-1, TRAV8-2, TRAV8-3, TRAV13-1, TRAV12-2, TRAV8-4, TRAV8-5, TRAV13-2, TRAV14DV4, TRAV9-2, TRAV15, AC245505.1, TRAV12-3, TRAV8-6, TRAV16, TRAV17, TRAV18, TRAV19, AC245505.2, TRAV20, TRAV21, AC245505.3, TRAV22, TRAV23DV6.
- chr16:30,471,587–31,603,531, 109 genes, copy number 3 (broad region; genes not listed).
- chr17:3,923,870–6,556,555, 99 genes, copy number 4 (broad region; genes not listed).
- chr17:12,991,612–19,214,045, 247 genes, copy number 4 (within-gene range 1–4) (broad region; genes not listed).
- chr17:21,197,954–22,424,731, 34 genes, copy number 4: TMEM11, AC087294.1, RN7SL426P, NATD1, EIF1P5, MAP2K3, KCNJ12, LINC02693, AC068418.3, PDLIM1P2, AC068418.2, AC068418.1, RPL21P120, AC233702.5, AC233702.7, AC233702.8, AC233702.6, AC233702.3, AC233702.2, AC233702.1, AC233702.4, AC233702.9, KCNJ18, ABBA01006766.1, NCOR1P2, UBBP4, FTLP13, LINC02002, AC138761.1, AC138761.2, FAM27E5, AC087575.1, FLJ36000, AC132825.3.
- chr17:68,511,780–74,314,884, 82 genes, copy number 3 (broad region; genes not listed).
- chr17:74,466,399–83,240,804, 407 genes, copy number 3–5 (broad region; genes not listed).
- chr20:32,355,053–64,327,972, 805 genes, copy number 3–4 (broad region; genes not listed).
- chr22:15,282,557–17,570,078, 95 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr22:18,029,385–50,801,309, 1,243 genes, copy number 3–4 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 24,494. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
